Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9GW, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9GW-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: M
Reported:
Submitting Physician:
Pathologist:
Intraop Pathologist:
Performing Physician:

Service:

Received:

ICD-03

Carcinoma, hepatocellular NOS
8170/3

Site Liver C22.0

JA 4/28/14

CLINICAL HISTORY:
NONE GIVEN.

PREOPERATIVE DIAGNOSIS:
HEPATOCELLULAR CARCINOMA.

SPECIMEN TYPE(S):
A: PORTAL HEPATIC LYMPH NODE FS
B: PORTION OF LEFT LOBE LIVER

FINAL DIAGNOSIS:
A. LYMPH NODE, PORTAL HEPATIC, EXCISION:
Lymph node with reactive changes and no evidence of malignancy.
B. LIVER, PORTION OF LEFT LOBE, RESECTION:
Hepatocellular carcinoma, moderately differentiated.

KEY PATHOLOGICAL FINDINGS:

Specimen type:	Partial resection.
Tumor configuration:	Irregular, ill defined.
Tumor size:	4.5 x 4.4 cm.
Histologic type:	Hepatocellular carcinoma.
Histologic grade:	Moderately differentiated.
Tumor necrosis:	Minimal (less than 1%).
Perineural invasion:	Not identified.
Paraneural margin:	Free of tumor.
Bile duct margin:	Not applicable.
Angiolymphatic invasion:	Not identified.
Additional pathologic findings:	Cirrhosis and fatty changes, and bile duct.
Hamartoma. Lymph nodes:	Porta hepatis lymph node, negative of tumor.
Pathologic stage:	T1 NO MX. Yes.

I, , the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically Signed out by

OTHER RELATED CLINICAL DATA:
NA

INTRAOPERATIVE DIAGNOSIS:
FROZEN SECTION DIAGNOSIS

FS#1. LYMPH NODE:
Free of malignancy.

COMMENT: This frozen section diagnosis/result was communicated to and acknowledged by
in at

[page 2 of 2]
I, _____, have performed the intraoperative consultation(s) and issued the above diagnoses.

GROSS DESCRIPTION:

- A. The specimen is received fresh and labeled "portohepatic lymph node". The specimen consists of a single, ovoid, soft-to-rubbery lymph node measuring 2.0 x 1.0 x 0.8 cm, which is submitted entirely for frozen section as PSA.
- B. Specimen B labeled "portion of left lobe of liver". The specimen consists of a 717 gram, unoriented portion of liver parenchyma which is measuring 24 x 14 x 7.5 cm. The capsule of liver is variegated, tan-pale-yellow to tan-red-brown, granular, with multiple subcapsular hemorrhages ranging from 0.1 to 0.3 cm in greatest dimension. The resection margin of the specimen is unstapled and reveals a tan-red-brown, focally cauterized liver parenchyma. Prior to sectioning the resection margin is inked black. On sectioning the specimen reveals an irregular, ill-defined rubbery to firm, intraparenchymal tumor, which measures 4.5 x 4.0 x 4.0 cm. The tumor is partially involving the capsule and is 0.7 cm from the closest inked resection margin. The cut surface of the tumor is tan-white to tan-pink, lobulated, without evidence of necrosis or hemorrhage. The remaining liver parenchyma is dark-red-brown and granular. There are no other lesions grossly identified. Representative sections of the specimen are submitted to the Tissue Procurement Laboratory. Representative sections of the specimen are submitted in 4 cassettes as follows:
- B1-B2: Tumor involving the capsule
- B3-B5: Representative sections of the tumor with closest resection margin
- B6-B7: Soft capsular areas of hemorrhage
- B8: Uninvolved liver parenchyma.

Source: NCI Genomic Data Commons file 7ea7909d-e1ee-445c-9292-83242483a8f9 (TCGA-2Y-A9GW.5846FA3D-E3AD-4530-8A5F-5D90CD17F539.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).